Somatic mutation profile of tumor specimen TCGA-WK-A8Y0-01A (aliquot TCGA-WK-A8Y0-01A-11D-A417-09) from TCGA case TCGA-WK-A8Y0, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 49.9 years (18,233 days).
Specimen TCGA-WK-A8Y0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a02f5fd-403c-4c46-9a3b-5bd71efea219.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WK-A8Y0-10D (Blood Derived Normal), aliquot TCGA-WK-A8Y0-10D-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/071d9c2e-3a14-491a-873c-ed4892f9ba8d

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Nonsense Mutation 4, Frame Shift Del 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 63/95 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACLY | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100709798; called by muse, mutect2, varscan2
- ADGRE3 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV99506859; called by muse, mutect2, varscan2
- ANO2 | c.1001C>T p.A334V (on ENST00000356134 / NM_001278597.3; = p.A338V on NM_001278596.3) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1469255109, COSV100501545; called by muse, mutect2, varscan2
- ATRX | c.5101A>T p.K1701* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as COSV100971627; called by muse, mutect2, varscan2
- C12orf42 | c.489C>G p.N163K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.132); catalogued as COSV100173051; called by muse, mutect2, varscan2
- CHST10 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99959305; called by muse, mutect2, varscan2
- CNTRL | c.5126A>G p.N1709S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV99444217; called by muse, mutect2, varscan2
- FSCB | c.48C>G p.H16Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV100470010; called by muse, mutect2, varscan2
- HUNK | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99529067; called by muse, mutect2, varscan2
- KEL | c.2052G>C p.K684N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as COSV100787350; called by muse, mutect2, varscan2
- LRP2 | c.719T>A p.V240D | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99790706; called by muse, mutect2, varscan2
- OR7G1 | c.507C>A p.C169* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99528789; called by muse, mutect2, varscan2
- PAPPA2 | c.1358A>T p.D453V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100867264; called by muse, mutect2, varscan2
- PRDM14 | c.1557C>A p.C519* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV52575979; called by muse, mutect2
- RNF213 | c.2587A>G p.K863E | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV100174117; called by muse, mutect2, varscan2
- SASH1 | c.1547G>A p.S516N | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100821530; called by muse, mutect2, varscan2
- SPACA3 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as COSV52190265, COSV52190926, COSV99284327; called by muse, mutect2, varscan2
- SPIRE2 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100989060; called by muse, mutect2
- TP53 | c.1002del p.R335Vfs*10 | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | catalogued as COSV99439495; called by mutect2, pindel, varscan2
- TPR | c.5201C>T p.P1734L | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV100824294; called by muse, mutect2, varscan2
- TTC7A | c.2497G>C p.V833L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs1195221566, COSV99767073; called by muse, mutect2, varscan2
- UQCRC1 | c.535A>G p.M179V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs772081605, COSV99179033; called by muse, mutect2, varscan2
- USH2A | c.5306T>G p.L1769R | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100244048; called by muse, mutect2, varscan2
- USP24 | c.5057C>T p.S1686L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as COSV99601247; called by muse, mutect2, varscan2
- VCX3A | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.279); catalogued as rs1469270035; called by mutect2, varscan2
- ZNF831 | c.4439C>A p.T1480N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100926327; called by muse, mutect2, varscan2
- ZRANB3 | c.1177G>C p.A393P | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747087140, COSV99925108; called by muse, mutect2, varscan2
- RB1 | c.1722_1725del p.K574Nfs*36 | Frame Shift Del (DEL) | VAF 42/74 reads (57%) | called by mutect2, pindel, varscan2
- SBNO2 | c.2349_2355del p.R783Sfs*5 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- BICDL1 | c.1434T>C p.I478= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99986010; called by mutect2, varscan2
- FAT1 | c.1500C>T p.Y500= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV101499692; called by muse, mutect2, varscan2
- GFRA3 | c.546C>T p.Y182= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV51230299, COSV99218589; called by muse, mutect2, varscan2
- MERTK | c.777C>T p.V259= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1418422196, COSV99775463; called by muse, mutect2, varscan2
- MTMR1 | c.1494T>A p.S498= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV100953169; called by muse, mutect2, varscan2
- NLRP12 | c.195G>T p.G65= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100146068; called by muse, mutect2, varscan2
- PON3 | c.702C>T p.V234= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99672790; called by muse, mutect2, varscan2
- SHROOM4 | c.3231G>A p.R1077= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99174948; called by muse, mutect2, varscan2
- SLC20A1 | c.723C>T p.F241= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99734330; called by muse, mutect2, varscan2
- TRRAP | c.10645C>T p.L3549= (on ENST00000359863 / NM_001244580.1; = p.L3520= on NM_003496.3) | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100723191; called by muse, mutect2, varscan2
- ZMYM1 | c.3072C>T p.I1024= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV100721108; called by muse, mutect2, varscan2
- DCHS2 | n.2733C>T | RNA (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100253545; called by muse, mutect2, varscan2
